Somatic mutation profile of tumor specimen c2db7236-990c-42b6-9ffb-2ad150 (aliquot c2db7236-990c-42b6-9ffb-2ad150_D6) from CPTAC case 15CO001, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen c2db7236-990c-42b6-9ffb-2ad150: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11edbfd5-540d-4489-a0c5-0c65deea8b8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 7e71d580-cbc5-4ced-938a-a2d9b9 (Blood Derived Normal), aliquot 7e71d580-cbc5-4ced-938a-a2d9b9_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef01d71b-aef0-4134-8dfa-c3a8f241b446

The open-access MAF lists 106 somatic variants for this specimen: 69 protein-altering or splice-affecting, 24 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 24, Nonsense Mutation 6, 5'UTR 4, Frame Shift Ins 3, 3'UTR 3, In Frame Del 3, Intron 3, RNA 3, Splice Region 2, Splice Site 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL12A1 | c.4957+1G>A p.X1653_splice | Splice Site (SNP) | VAF 44/117 reads (38%) | catalogued as rs1366112521, COSV59395045; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 59/203 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455dup p.P153Afs*28 | Frame Shift Ins (INS) | VAF 149/496 reads (30%) | catalogued as rs730882019, COSV53468298, COSV99394349; ClinVar: pathogenic; called by pindel, varscan2
- ABCB4 | c.1657A>G p.I553V | Missense Mutation (SNP) | VAF 101/264 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1411802910; called by muse, mutect2, varscan2
- AKR1C2 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs374218894; called by muse, mutect2, varscan2
- ARHGAP39 | c.2051C>T p.T684M | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs978211816; called by muse, mutect2, varscan2
- ATG2B | c.4177C>T p.R1393* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as rs1486909707; called by muse, mutect2, varscan2
- B3GAT3 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 217/363 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs771622019; called by muse, mutect2, varscan2
- BAIAP2L2 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 90/274 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1300085477, COSV60201804; called by mutect2, varscan2
- BTN3A3 | c.1020G>A p.A340= | Splice Region (SNP) | VAF 45/111 reads (41%) | catalogued as rs200780915; called by muse, mutect2, varscan2
- CACNA1G | c.3619C>T p.R1207C | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs775810943, COSV100661719, COSV61741215; called by muse, mutect2
- DCAF12L2 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 15/268 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs776346189, COSV63582048; called by muse, mutect2
- EBAG9 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs199580138; called by muse, mutect2, varscan2
- EEA1 | c.2373dup p.S792Ifs*2 | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | catalogued as rs748616362; called by mutect2, pindel
- GPC2 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1431239553; called by muse, mutect2, varscan2
- HS3ST2 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1254269360; called by muse, mutect2
- IGHD | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 197/594 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.374); catalogued as rs373899047; called by muse, mutect2, varscan2
- KCNK9 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs149047706; called by muse, mutect2, varscan2
- LILRA1 | c.628C>A p.L210I | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as COSV52180362; called by muse, mutect2, varscan2
- LRRC4C | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 148/486 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs778049301; called by muse, mutect2, varscan2
- MTOR | c.4541G>T p.R1514L | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as COSV63870590; called by muse, mutect2, varscan2
- MYO15A | c.1879G>A p.V627M | Missense Mutation (SNP) | VAF 70/115 reads (61%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs1187589732; called by muse, mutect2, varscan2
- NRXN1 | c.4183C>T p.R1395W | Missense Mutation (SNP) | VAF 102/253 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs749698919, COSV60499062; called by muse, mutect2, varscan2
- OR4B1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 134/349 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as rs550081185, COSV58883016; called by muse, mutect2, varscan2
- RASSF4 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 117/311 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs200147715, COSV53584646; called by muse, mutect2, varscan2
- SEMA5B | c.2291C>T p.T764M | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.946); catalogued as rs1277731715; called by muse, mutect2
- SLC35A3 | c.*692A>T | Splice Region (SNP) | VAF 10/28 reads (36%) | catalogued as CS1310457; called by muse, mutect2, varscan2
- TAF1 | c.1736G>A p.R579Q (on ENST00000373790 / NM_138923.4; = p.R600Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV99334068; called by muse, mutect2, varscan2
- TP53 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 138/323 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs750600586, CM123559, COSV52661339, COSV52708439, COSV53502932; ClinVar: uncertain significance; called by muse, varscan2
- UBE2I | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 86/228 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as rs1335800928, COSV57647814; called by muse, mutect2, varscan2
- USP19 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 113/289 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs764830954, COSV59738505; called by muse, varscan2
- USP9X | c.5459G>A p.R1820Q | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61073972; called by muse, mutect2, varscan2
- VWA7 | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 91/280 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.577); catalogued as rs1029490631, COSV65173592; called by muse, mutect2, varscan2
- WWC3 | c.2279C>T p.T760M | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs753360477; called by muse, mutect2, varscan2
- XK | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 115/489 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs367651585, COSV101064639; called by muse, mutect2, varscan2
- ZMYM2 | c.1121T>C p.V374A | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs1363307045; called by muse, mutect2, varscan2
- ABCA12 | c.4385C>A p.T1462N (on ENST00000272895 / NM_173076.3; = p.T1144N on NM_015657.3) | Missense Mutation (SNP) | VAF 118/290 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- ADCY8 | c.1196A>G p.Q399R | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- ASAP3 | c.970A>T p.K324* | Nonsense Mutation (SNP) | VAF 59/175 reads (34%) | called by muse, mutect2, varscan2
- ASPHD2 | c.636C>A p.C212* | Nonsense Mutation (SNP) | VAF 20/222 reads (9%) | called by muse, mutect2
- ATP6V1C1 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CASKIN1 | c.3190_3225del p.R1064_A1075del | In Frame Del (DEL) | VAF 51/350 reads (15%) | called by mutect2, pindel, varscan2
- CEP350 | c.2651A>C p.D884A | Missense Mutation (SNP) | VAF 125/335 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CWC22 | c.1741A>G p.I581V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DGKI | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 49/138 reads (36%) | called by muse, mutect2, varscan2
- DMD | c.3667A>G p.S1223G | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- ERO1B | c.1283dup p.S429Ifs*2 | Frame Shift Ins (INS) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- FAM47A | c.1690C>G p.P564A | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- LVRN | c.1121C>A p.P374H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MBOAT2 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MCM3 | c.1462C>T p.R488* (on ENST00000229854 / NM_001366374.2; = p.R478* on NM_002388.6 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 59/174 reads (34%) | called by muse, mutect2, varscan2
- MST1 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 186/461 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO1C | c.2553C>A p.C851* (on ENST00000648651 / NM_001080779.2; = p.C816* on NM_033375.5) | Nonsense Mutation (SNP) | VAF 143/415 reads (34%) | called by muse, mutect2, varscan2
- NPR1 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, varscan2
- ORC3 | c.580A>C p.K194Q | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PCDH11X | c.2292del p.S764Rfs*3 | Frame Shift Del (DEL) | VAF 146/424 reads (34%) | called by mutect2, pindel*, varscan2
- PCDHGB4 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIGA | c.849-1G>C p.X283_splice | Splice Site (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- PIK3R1 | c.1699_1703delinsTT p.K567_P568delinsL (on ENST00000521381 / NM_181523.3; = p.K297_P298delinsL on NM_181504.4) | In Frame Del (DEL) | VAF 25/85 reads (29%) | called by pindel, varscan2*
- PTHLH | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 35/356 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- RBM26 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- RIOX2 | c.675G>A p.M225I | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC2A1 | c.577A>T p.I193F | Missense Mutation (SNP) | VAF 211/658 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SMC5 | c.1574_1575del p.K525Rfs*4 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by pindel, varscan2
- SOX17 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 88/489 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SRSF12 | c.323A>C p.D108A | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TTC21B | c.2585C>T p.A862V | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- UBAP2L | c.2755G>A p.G919S | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USF3 | c.442_444del p.I148del | In Frame Del (DEL) | VAF 46/118 reads (39%) | called by pindel, varscan2
- APMAP | c.54C>T p.V18= | Silent (SNP) | VAF 48/92 reads (52%) | called by muse, mutect2, varscan2
- ASB3 | c.339G>A p.T113= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs1425729712, COSV55078058; called by muse, mutect2, varscan2
- CALD1 | c.1479G>A p.S493= (on ENST00000361675 / NM_033138.4; = p.S238= on NM_004342.7) | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs758682592, COSV62645073; called by muse, mutect2, varscan2
- CELSR2 | c.1515C>T p.F505= | Silent (SNP) | VAF 171/454 reads (38%) | catalogued as rs371030910; called by muse, mutect2, varscan2
- CHGA | c.624G>A p.Q208= | Silent (SNP) | VAF 86/294 reads (29%) | called by muse, varscan2
- DMRT3 | c.1284C>T p.R428= | Silent (SNP) | VAF 119/263 reads (45%) | catalogued as rs764166688, COSV51902493; called by muse, mutect2, varscan2
- FAM160A2 | c.1833G>A p.E611= (on ENST00000449352 / NM_001098794.2; = p.E625= on NM_032127.4) | Silent (SNP) | VAF 48/136 reads (35%) | called by muse, mutect2, varscan2
- GABRG2 | c.867C>T p.T289= (on ENST00000361925 / NM_001375343.1; = p.T249= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/168 reads (28%) | called by muse, mutect2, varscan2
- GALNT14 | c.378G>A p.T126= | Silent (SNP) | VAF 70/210 reads (33%) | catalogued as rs200313372; called by muse, mutect2, varscan2
- GRIA1 | c.1197C>T p.G399= | Silent (SNP) | VAF 66/163 reads (40%) | catalogued as rs772173588, COSV53614289; called by muse, mutect2, varscan2
- HLA-G | c.519G>A p.A173= | Silent (SNP) | VAF 48/800 reads (6%) | catalogued as COSV64406998; called by muse, mutect2
- HNF1A | c.921G>A p.L307= | Silent (SNP) | VAF 93/212 reads (44%) | called by muse, mutect2, varscan2
- IRX2 | c.1167C>T p.Y389= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as rs762137935; called by muse, mutect2, varscan2
- KCNC1 | c.345C>T p.A115= | Silent (SNP) | VAF 21/381 reads (6%) | catalogued as COSV56395262; called by muse, mutect2
- LHX5 | c.1191C>T p.N397= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs1321195020; called by muse, mutect2, varscan2
- MBD3 | c.696G>A p.V232= | Silent (SNP) | VAF 186/369 reads (50%) | called by muse, varscan2
- MYH13 | c.4839C>T p.N1613= | Silent (SNP) | VAF 149/238 reads (63%) | catalogued as rs753157072, COSV99355353; called by muse, mutect2, varscan2
- NAPSA | c.699G>T p.L233= | Silent (SNP) | VAF 93/284 reads (33%) | called by muse, mutect2, varscan2
- NLRP12 | c.2127G>A p.L709= | Silent (SNP) | VAF 38/540 reads (7%) | catalogued as rs1053502306; called by muse, mutect2
- OR8S1 | c.1050G>A p.A350= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs1218074190; called by muse, mutect2, varscan2
- RADX | c.615C>T p.D205= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- TET2 | c.426C>T p.S142= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs540228872, COSV54396924; called by muse, mutect2, varscan2
- TMEM178B | c.576C>A p.G192= | Silent (SNP) | VAF 80/278 reads (29%) | called by muse, mutect2, varscan2
- TUBB4A | c.1197G>A p.T399= | Silent (SNP) | VAF 240/710 reads (34%) | catalogued as rs1568409099; called by muse, mutect2, varscan2
- ABCC6P2 | n.10G>T | RNA (SNP) | VAF 24/48 reads (50%) | called by mutect2, varscan2
- ANO3 | c.-20C>T | 5'UTR (SNP) | VAF 18/169 reads (11%) | called by muse, mutect2
- APEX2 | c.-31C>T | 5'UTR (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- BLACE | n.1604A>T | RNA (SNP) | VAF 177/491 reads (36%) | called by muse, mutect2, varscan2
- BRAF | c.980+44G>A | Intron (SNP) | VAF 43/121 reads (36%) | catalogued as rs372663526; called by muse, mutect2, varscan2
- CD4 | c.*5C>T | 3'UTR (SNP) | VAF 76/234 reads (32%) | catalogued as rs202082987; called by muse, mutect2
- CETN2 | c.-35G>A | 5'UTR (SNP) | VAF 27/111 reads (24%) | catalogued as COSV100938613; called by muse, mutect2, varscan2
- DNAJB2 | c.*970C>T | 3'UTR (SNP) | VAF 60/171 reads (35%) | called by muse, mutect2, varscan2
- FAM126A | c.992-856T>A | Intron (SNP) | VAF 65/182 reads (36%) | called by muse, mutect2, varscan2
- HECTD2 | c.-20C>T | 5'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- HPS3 | c.*6T>C | 3'UTR (SNP) | VAF 136/341 reads (40%) | called by muse, varscan2
- MIR222 | n.8G>T | RNA (SNP) | VAF 10/127 reads (8%) | called by muse, mutect2
- VIPR2 | c.51+195C>T | Intron (SNP) | VAF 7/117 reads (6%) | catalogued as rs1451946731; called by muse, mutect2
